Gene-level copy-number profile of tumor specimen TCGA-M9-A5M8-01A from TCGA case TCGA-M9-A5M8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 58.7 years (21,433 days).
Specimen TCGA-M9-A5M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.3e96e555-bb15-464d-9e87-06ba44ce465d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-M9-A5M8-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/fef1775f-9bdc-4802-ad88-8a4a981abbd6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 17,662; copy number 2: 39,357; copy number 3: 2,589; copy number 4: 38; copy number 5: 23; copy number 6: 45; copy number 11: 47; copy number 12: 19; copy number 17: 27.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-M9-A5M8-01A-11D-A28A-01): tumor purity 0.63, ploidy 1.77, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:59,314,110–59,314,800, 1 gene: AC008833.1.
- chr18:50,879,080–51,085,045, 5 genes (within-gene range 0–1): ME2, Y_RNA, ELAC1, AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 161 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:39,566,915–42,021,376, 161 genes, copy number 5–17 (within-gene range 3–17) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 15,241. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
